Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RE-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3
carcinoma, squamous cell, large cell keratinizing 8071/3
Site: cervix, NOS C53.9 9/8/11

SURGICAL PATHOLOGY

SURGERY CASE #: FINAL

DATE OF SURGERY:

SURGEON:

SPECIMEN:

- A. Pelvic washings
- B. Right external iliac lymph nodes
- C. Right obturator lymph nodes
- D. Right common periaortic lymph nodes
- E. Left external iliac lymph nodes
- F. Left obturator lymph nodes
- G. Left common periaortic lymph nodes
- H. Cervix, vagina, parametria
- I. Posterior vaginal mucosa

FROZEN SECTION DIAGNOSIS: B. Five lymph nodes, no malignancy. Reactive follicular hyperplasia.

- D. Two lymph nodes, no malignancy.
- C. Four lymph nodes, benign.
- E. Five lymph nodes, no malignancy.
- F. Three lymph nodes, no malignancy.
- G. Two lymph nodes, no malignancy.

OPERATIVE PROCEDURE: Laparoscopic radical trachelectomy, pelvic/periaortic lymph node dissection
PREOPERATIVE DIAGNOSIS: Invasive squamous cell carcinoma of the vulva, cervix cancer stage T1B1
POSTOPERATIVE DIAGNOSIS: Pending pathology

*****DIAGNOSIS*****

1. Type of specimen:
Uterine cervix with right and left parametria, portion of vagina, pelvic washings and regional lymph nodes; laparoscopic radical trachelectomy with staging lymph node dissection.
2. Tumor type and grade:
Cervical squamous cell carcinoma, large cell keratinizing, invasive and in situ, moderately differentiated.
3. Depth of invasion:
The tumor extends to a depth of 9.5 mm.
A. The thickness of the cervix in the area of maximal tumor invasion is more than 25 mm.
4. Tumor size:
The tumor measures 5.8 cm in largest diameter.

[page 2 of 4]
P:

MMR

5. Tumor site:
Cervix, circumferential.
6. Extent:
A. Vascular invasion:
1. Small vessel invasion present.
2. Large vessel invasion: not identified.
B. Vaginal extension: not identified.
C. Uterine corpus extension: not identified.
D. Parametrial involvement, right and left: Not identified.
7. Margins:
A. Vaginal: negative.
B. Parametrial; negative.
8. Lymph nodes:
Negative.
Five right external iliac lymph nodes, no malignancy found (0/5)
Four right obturator lymph nodes, no malignancy found (0/4)
Two right common periaortic lymph nodes, no malignancy found (0/2)
Five left external iliac lymph nodes, no malignancy found (0/5)
Three left obturator lymph nodes, no malignancy found (0/3)
Two left common periaortic lymph nodes, no malignancy found (0/2)
TOTAL: 0/21
9. Pelvic washings:
Negative.
10. Additional findings:
Reactive lymphoid hyperplasia.
11. Tissue is submitted for . Yes including frozen
neoplastic and normal cervical tissue and parafin blocks including
normal cervical (block 4) and neoplastic (block 9) tissue.
- 11 TNM STAGING :
pT2a2: Clinically visible lesion more than 4 cm in greatest
dimension.
pNO (0/21).
pMX
- A. 88108 B. 88307, 88331 C. 88307, 88331 D. 88307,
88331 E. 88307, 88331
F. 88307, 88331 G. 88307, 88331 H. 88309. I. 88302

MICROSCOPIC EXAMINATION:

A microscopic examination was performed to render the above diagnoses.

GROSS:

- A. Received approximately 15 cc of yellow, watery fluid. Two cytospins obtained.
- B. The specimen is received in fixative in a single container, labeled

[page 3 of 4]
with the patient's name, number and marked as "right external iliac lymph nodes". It consists of fragments of fibroadipose tissue with lymph nodes in aggregate 4.5 x 3.5 x 1.3 cm. The lymph nodes range in size from 0.5 to 2.5 cm and appear grossly free of metastatic tumor. The lymph nodes are submitted for frozen section, frozen section permanent in a single cassette. Touch preparations are obtained.

C. The specimen is received in fixative in a single container, labeled with the patient's name, number and marked as "right obturator lymph nodes". It consists of fragments of fibroadipose tissue with lymph nodes in aggregate 6 x 1 x 0.8 cm. The lymph nodes are grossly free of tumor and are submitted in a single cassette for frozen section, frozen section permanent. Touch preparations are obtained.

D. The specimen is received in fixative in a single container, labeled with the patient's name, number and marked as "right common periaortic lymph nodes". It consists of fragments of fibroadipose tissue with lymph nodes in aggregate 2 x 2 x 1 cm. The lymph nodes are grossly unremarkable, measuring up to 0.9 cm in diameter and are submitted for frozen section, frozen section permanent in a single cassette. Touch preparations are obtained.

E. The specimen is received in fixative in a single container, labeled with the patient's name, number and marked as "left external iliac lymph nodes". It consists of fragments of fibroadipose tissue with lymph nodes in aggregate 4 cm. The lymph nodes are grossly free of tumor, measuring up to 2 cm in diameter and are submitted for frozen section, frozen section permanent in a single cassette. Touch preparations are obtained.

F. The specimen is received in fixative in a single container, labeled with the patient's name, number and marked as "left obturator lymph nodes". It consists of fragments of fibroadipose tissue with lymph nodes in aggregate 4.5 x 2 x 0.5 cm. The lymph nodes are grossly unremarkable, measuring up to 1 cm in diameter and are submitted for frozen section, frozen section permanent in a single cassette. Touch preparations are obtained.

G. The specimen is received in fixative in a single container, labeled with the patient's name, number and marked as "left common periaortic lymph nodes". It consists of fragments of fibroadipose tissue with lymph nodes in aggregate 2 cm. The lymph nodes are grossly unremarkable measuring up to 1.5 cm in diameter and are submitted for frozen section, frozen section permanent in a single cassette. Touch preparations are obtained.

H. The specimen is received fresh in a single container, labeled with the patient's name, number and marked as "cervix, vagina, parametria". It consists of a radical trachelectomy specimen which includes the cervix measuring 4.5 cm in circumference and 2.5 cm in length in continuity with right and left parametria to a maximum thickness of 2.5 cm and a circumferential vaginal cuff up to 2.5 cm. Growing from the squamocolumnar junction and extensively involving the ectocervix is a fungating, foul-smelling, ulcerated, 5.8 x 4 cm mass that protrudes up to 1.4 cm above the flat cervical surface. The cervical and vaginal resection margins are grossly free of

[page 4 of 4]
tumor. The right and left parametria are also grossly free of tumor. The cervix is pinned down, flat and fixed prior to sectioning. Representative sections are submitted as follows:

Sections:

#1 - Cervical tangential resection margin, 12 to 3 - yellow, 3 to 6 - black for frozen section, frozen section permanent. Touch preparations are obtained.

#2 - Cervical tangential margin, 6 to 9 - black and 9 to 12 - yellow.

#3 - Vaginal resection margins, 12 to 3 and 3 to 6 o'clock tangential.

#4 - Vaginal resection margins, 6 to 9, 9 to 12 o'clock.

#5 and #6 - Right parametrium.

#7 and #8 - Left parametrium.

#9 through #14 - Cervix, proceeding from 12 to 12 o'clock positions clockwise.

I. The specimen is received fresh in a single container, labeled with the patient's name, number and marked as "posterior vaginal mucosa". It consists of two tan portions of mucosa measuring 1.2 x 1.1 x 0.3 cm in aggregate dimension. The larger portion is bisected. Both portions are totally submitted in a single cassette.

Electronically Signed by

Page created:

Fac.
User

Source: NCI Genomic Data Commons file 69d7015d-e279-4f3c-baf4-598d207d783f (TCGA-EK-A2RE.86AFFE75-2DB8-40E3-9BCA-A2F695173DCC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).